Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOE, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAOE-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Seminoma NOS 9061/3
Site: R Testis NOS C62.9.
W 3/31/14

SURGICAL PATH []

Order Dr:

Order Clinic:

Order Dx: TESTICULAR MASS

Specimen Source: R TESTICLE R CORD

CASE NO.:

GROSS EXAM DATE:

PHYSICIAN & PAGER #:

-- CONCLUSION/DIAGNOSTIC CODE -----
NON-ROUTINE

-- REPORT -----

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA (5.5 cm), right testis (A), radical orchiectomy. (See note)
2. LYMPHOVASCULAR INVASION NOT IDENTIFIED.
3. NO INVASION OF EPIDIDYMIS NOTED.
4. TUMOR LIMITED TO TESTIS.
5. MARGINS FREE OF TUMOR, distal right spermatic cord (B).
6. INTRATUBULAR GERM CELL NEOPLASIA.
7. pT1NXMX.
8. TESTICULAR TISSUE WITH TUBULAR ATROPHY AND FOCAL EVIDENCE OF SPERMATOGENESIS.

Note: Tumor is C-kit positive and CAM5.2 negative.

GROSS DESCRIPTION:

The specimen is received in two parts.

Specimen part A is received fresh from the operating room and labeled with the patient's name, medical record number and "right testicle." It consists of 110-gram orchiectomy specimen, including a 6.5 x 5.5 x 4-cm testis, a 3 x 2.5 x 1-cm epididymis, and a 6.9 cm in length and 1 cm diameter spermatic cord. The specimen is bivalved and fixed overnight; 0.3 cm from the base of the epididymis and 0.5 cm from the tunica albuginea is a 5.5 x 5 x 4-cm white-tan, fleshy well-circumscribed mass with no areas of hemorrhage or necrosis. There is no gross involvement of the tunica albuginea or impingement on the epididymis. The rim of testicular parenchyma at the edge of the tumor

[page 2 of 2]
-- REPORT --

is compressed and grossly unremarkable. The spermatic cord consists of vas deferens, arteries, and veins, and unremarkable. R12. Summary of cassettes:

- 1 to 5. Tumor.
6. Tumor and base of epididymis.
7. Tumor and tunica vaginalis.
- 8 to 9. Tumor and adjacent testis.
10. Spermatic cord resection margin.
11. Spermatic cord midportion.
12. Spermatic cord peritesticular portion.

Specimen part B is received fixed in formalin and labeled with the patient's name, medical record number and "distal right spermatic cord suture on proximal end." It consists of a longitudinal fragment of brown soft tissue measuring 4.5 x 1.5 x 1.5 cm in greatest dimension. The black suture is grossly identified, which indicates the proximal end. Serial section from the proximal end reveals no mass lesion. Representative sections are taken. R2. Summary of cassettes:

1. Proximal end.
2. Distal end.

Source: NCI Genomic Data Commons file 8db880a3-e306-4b06-8bd3-7c549cf14793 (TCGA-XE-AAOE-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).